Somatic mutation profile of tumor specimen C3N-01814-01 (aliquot CPT0167860007) from CPTAC case C3N-01814, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.8 years (17,813 days).
Specimen C3N-01814-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660820e0-f7ba-444e-9149-f9cce8dc7c32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01814-71 (Blood Derived Normal), aliquot CPT0167920004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40e7ed37-04ff-4e90-890c-0fda30381a19

The open-access MAF lists 100 somatic variants for this specimen: 70 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 16, Intron 8, Splice Site 4, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.1134_1135del p.D380* | Frame Shift Del (DEL) | VAF 62/305 reads (20%) | catalogued as rs876660549, COSV52274500; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 187/233 reads (80%) | hotspot (GDC flag); catalogued as rs1057517809, CS1413088, COSV64290834, COSV64293694, COSV64298429; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 74/298 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF15 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.383); catalogued as COSV62725994; called by muse, mutect2, varscan2
- CCDC80 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs140232948; called by muse, mutect2, varscan2
- CDCP1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs750220191, COSV56105509; called by muse, varscan2
- CDH18 | c.1577T>A p.F526Y | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV56906184; called by muse, mutect2, varscan2
- CHL1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs752378415, COSV56595004, COSV99851945; called by muse, mutect2, varscan2
- CNTNAP5 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760393085, COSV70494162, COSV70518021; called by muse, mutect2, varscan2
- COQ2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752363398, CM154312; called by muse, mutect2, varscan2
- DGKI | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 119/383 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1222093392, COSV99933351; called by muse, mutect2, varscan2
- DNAH2 | c.4877G>A p.R1626Q | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs530683645; called by muse, mutect2, varscan2
- GPAT2 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756153213, COSV64003017; called by muse, mutect2, varscan2
- GRB10 | c.943C>T p.R315W (on ENST00000398812; = p.R257W on NM_001001550.3) | Missense Mutation (SNP) | VAF 153/533 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs368562566, COSV60013682; called by muse, mutect2, varscan2
- HP | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs104894517, CM040754; ClinVar: affects; called by muse, mutect2, varscan2
- KRT33A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 149/403 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as rs754832467, COSV50371693; called by muse, mutect2, varscan2
- MAPK15 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs35285081; called by muse, mutect2, varscan2
- MDM2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs867680779, COSV50700389; called by muse, mutect2, varscan2
- MTMR7 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs374948754; called by muse, mutect2, varscan2
- MUC17 | c.11557G>A p.G3853S | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.725); catalogued as rs146665354; called by muse, mutect2, varscan2
- NDNF | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV65634498; called by muse, mutect2, varscan2
- NPVF | c.129A>T p.K43N | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV56060742; called by muse, mutect2
- OR10H5 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs1202097564; called by muse, mutect2, varscan2
- PHIP | c.4991A>C p.K1664T | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51510325; called by muse, mutect2, varscan2
- PRR23A | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV67213743; called by muse, mutect2, varscan2
- PTPRD | c.3993G>A p.M1331I | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV61992450; called by muse, mutect2, varscan2
- RASIP1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 239/573 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1303689495; called by muse, mutect2, varscan2
- TBXT | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs552884807; called by muse, mutect2, varscan2
- TRIB3 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs781183054, COSV53932917; called by muse, mutect2, varscan2
- ZNF280A | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV57479599; called by muse, mutect2, varscan2
- ZNF804A | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs750195715, COSV56440604, COSV56454409; called by muse, mutect2, varscan2
- ADGRL1 | c.1202C>T p.P401L (on ENST00000340736 / NM_001008701.3; = p.P396L on NM_014921.5) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2
- AGO1 | c.1460C>G p.P487R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AHR | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP10 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ATXN2L | c.2989C>T p.H997Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BHLHE23 | c.62C>A p.A21E (on ENST00000370346; = p.A37E on NM_080606.4) | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CACNA2D2 | c.207-1G>A p.X69_splice | Splice Site (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- CFH | c.2090T>A p.L697H | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CTBS | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DCDC1 | c.2458C>T p.L820F | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSG4 | c.1451G>T p.C484F | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EIF2AK3 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- FBXO40 | c.112T>A p.C38S | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLOD5 | c.478T>G p.S160A | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HUWE1 | c.7345G>T p.D2449Y | Missense Mutation (SNP) | VAF 65/368 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- INPPL1 | c.2119T>G p.Y707D | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13B | c.5099G>T p.W1700L | Missense Mutation (SNP) | VAF 170/366 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2B | c.4081G>T p.D1361Y | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ME2 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEF2D | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 94/281 reads (33%) | called by muse, mutect2, varscan2
- MMP14 | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MYMK | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOR1 | c.6199del p.Q2067Kfs*27 | Frame Shift Del (DEL) | VAF 69/202 reads (34%) | called by mutect2, pindel, varscan2
- OR13D1 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- OR52E6 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDK4 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R14C | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PTPRM | c.2522A>G p.Y841C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RAB4B | c.517A>T p.I173F | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- RPL5 | c.4-2A>G p.X2_splice | Splice Site (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- SALL3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCFD1 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 63/171 reads (37%) | called by muse, mutect2, varscan2
- SLITRK1 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SOD2 | c.23+1G>A p.X8_splice | Splice Site (SNP) | VAF 107/271 reads (39%) | called by muse, mutect2, varscan2
- TBC1D9 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- TG | c.7904C>T p.P2635L | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMCC3 | c.147C>A p.N49K | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM132B | c.2568del p.K857Rfs*33 | Frame Shift Del (DEL) | VAF 120/343 reads (35%) | called by mutect2, pindel, varscan2
- WWC1 | c.1067T>C p.F356S | Missense Mutation (SNP) | VAF 68/343 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- BIRC3 | c.555G>A p.S185= | Silent (SNP) | VAF 84/235 reads (36%) | catalogued as rs1250630759, COSV99679737; called by muse, mutect2, varscan2
- DPPA2 | c.207A>G p.Q69= | Silent (SNP) | VAF 53/126 reads (42%) | called by muse, mutect2, varscan2
- EIF2S3B | c.627G>A p.A209= | Silent (SNP) | VAF 145/351 reads (41%) | catalogued as rs778023052, COSV59370544; called by muse, mutect2, varscan2
- GNL3L | c.285C>G p.R95= | Silent (SNP) | VAF 69/196 reads (35%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.165G>A p.K55= | Silent (SNP) | VAF 87/229 reads (38%) | catalogued as COSV101534402, COSV72391645; called by muse, mutect2, varscan2
- MAGEB6B | c.123G>A p.S41= | Silent (SNP) | VAF 112/301 reads (37%) | catalogued as COSV69689609; called by muse, mutect2, varscan2
- OR4Q2 | c.225A>T p.S75= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- PCDH11X | c.3150G>A p.Q1050= | Silent (SNP) | VAF 120/307 reads (39%) | called by muse, mutect2, varscan2
- PIK3CG | c.2313T>C p.L771= | Silent (SNP) | VAF 52/177 reads (29%) | called by muse, mutect2, varscan2
- POGK | c.1596G>A p.A532= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs770826223, COSV63311745; called by muse, mutect2, varscan2
- PRRC2A | c.4107C>T p.S1369= | Silent (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- SMPD1 | c.978C>T p.V326= | Silent (SNP) | VAF 83/209 reads (40%) | called by muse, mutect2, varscan2
- TYR | c.879C>T p.P293= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as rs760287990, COSV54486952; called by muse, mutect2, varscan2
- UGT1A4 | c.600C>A p.T200= | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as rs755279919; called by muse, mutect2, varscan2
- ZNF648 | c.1248C>A p.G416= | Silent (SNP) | VAF 57/151 reads (38%) | called by muse, mutect2, varscan2
- ZNF813 | c.444G>C p.L148= | Silent (SNP) | VAF 123/341 reads (36%) | catalogued as COSV67178437; called by muse, mutect2, varscan2
- CASZ1 | c.-23-406G>A | Intron (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- CCNT2 | c.539+19T>G | Intron (SNP) | VAF 67/166 reads (40%) | called by muse, mutect2, varscan2
- EIF4A2 | c.909+81G>T | Intron (SNP) | VAF 79/228 reads (35%) | called by muse, mutect2, varscan2
- ELMO1 | c.-6del | 5'UTR (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel
- LINC01600 | n.699C>T | RNA (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- MFSD8 | c.1102+16del | Intron (DEL) | VAF 95/314 reads (30%) | called by mutect2, pindel, varscan2
- NDUFAF4 | c.-39A>T | 5'UTR (SNP) | VAF 31/372 reads (8%) | called by muse, mutect2
- OR2U1P | n.827T>A | RNA (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2
- ORC6 | c.562+63C>T | Intron (SNP) | VAF 112/233 reads (48%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.543G>A | RNA (SNP) | VAF 236/560 reads (42%) | catalogued as rs1453257192; called by muse, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12760C>T | Intron (SNP) | VAF 25/69 reads (36%) | catalogued as rs753670409, COSV101044327; called by muse, mutect2, varscan2
- THRA | c.1110+57A>G | Intron (SNP) | VAF 118/301 reads (39%) | called by muse, mutect2, varscan2
- TPM4 | chr19:16076071 C>T | 5'Flank (SNP) | VAF 87/217 reads (40%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.569-2182G>C | Intron (SNP) | VAF 62/153 reads (41%) | catalogued as rs999792133; called by muse, mutect2, varscan2
